Somatic mutation profile of tumor specimen TCGA-EB-A430-01A (aliquot TCGA-EB-A430-01A-11D-A24R-08) from TCGA case TCGA-EB-A430, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 83.1 years (30,344 days).
Specimen TCGA-EB-A430-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e07fcd97-4666-40b3-97c1-d6767482a10a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A430-10A (Blood Derived Normal), aliquot TCGA-EB-A430-10A-01D-A24R-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28bc99ec-34d9-4a25-8019-0126a7308660

The open-access MAF lists 479 somatic variants for this specimen: 328 protein-altering or splice-affecting, 137 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 296, Silent 137, Nonsense Mutation 20, RNA 6, Frame Shift Ins 4, Splice Site 3, Intron 3, 3'UTR 3, Frame Shift Del 2, Splice Region 2, 5'Flank 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/126 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CYP2U1 | c.1396C>T p.R466* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as rs766380148, COSV60549733; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABL1 | c.2753C>T p.P918L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs372727500; called by muse, mutect2, varscan2
- ACOT4 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs201663408, COSV58336389; called by muse, mutect2, varscan2
- ACSS3 | c.1455G>A p.M485I | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as rs989417666, COSV54087157; called by muse, mutect2, varscan2
- ACTL7B | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); catalogued as COSV65928207; called by muse, mutect2, varscan2
- ADAMTS2 | c.779A>G p.H260R | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.321); catalogued as COSV51106626; called by muse, mutect2, varscan2
- ADAMTS20 | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV67139948; called by muse, mutect2, varscan2
- ADCY1 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs1228715407, COSV52038929; called by muse, mutect2, varscan2
- ADGRE3 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV53735142; called by muse, mutect2, varscan2
- AKAP13 | c.7391G>A p.R2464K (on ENST00000394518 / NM_007200.5; = p.R2468K on NM_006738.6) | Missense Mutation (SNP) | VAF 91/274 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV63470604; called by muse, mutect2, varscan2
- ALDOB | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV66398712; called by muse, mutect2, varscan2
- ANK1 | c.2291G>A p.S764N | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs758480712, COSV55896519; called by muse, mutect2, varscan2
- ANK3 | c.12257C>T p.P4086L (on ENST00000280772 / NM_001320874.2; = p.P607L on NM_001149.3) | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV55083207; called by muse, mutect2, varscan2
- ANK3 | c.10279T>G p.L3427V | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV55083230; called by muse, mutect2, varscan2
- ANKRD24 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.02); catalogued as COSV53675964; called by muse, mutect2, varscan2
- ANKRD30A | c.898G>A p.E300K (on ENST00000611781; = p.E244K on NM_052997.2) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.931); catalogued as COSV64606483; called by muse, mutect2, varscan2
- AOX1 | c.3670C>T p.P1224S | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV53497231; called by muse, mutect2, varscan2
- ARHGEF28 | c.4238G>A p.G1413D | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as rs1473471505, COSV55271125; called by muse, mutect2, varscan2
- ARHGEF9 | c.956T>G p.L319R | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53644757; called by muse, mutect2, varscan2
- ARMC4 | c.2422G>A p.G808R | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.619); catalogued as rs753521915, COSV59470364; called by muse, mutect2, varscan2
- ARNT | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.041); catalogued as COSV62232414; called by muse, mutect2, varscan2
- ASTL | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV60905552; called by muse, mutect2, varscan2
- ATXN7L2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV63992976; called by muse, mutect2, varscan2
- AXDND1 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV62648856; called by muse, mutect2, varscan2
- B3GNT2 | c.1015T>G p.C339G | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57345931; called by muse, mutect2, varscan2
- BAAT | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52291127; called by muse, mutect2, varscan2
- C12orf54 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 50/117 reads (43%) | catalogued as rs760341392, COSV58360190; called by muse, mutect2, varscan2
- C6 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs267600638, COSV54704649; called by muse, mutect2, varscan2
- CAMKV | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 64/201 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56557936; called by muse, mutect2, varscan2
- CAPRIN2 | c.1693A>C p.I565L | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV51835869; called by muse, mutect2, varscan2
- CAV3 | c.223C>A p.L75M | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV57481077; called by muse, mutect2, varscan2
- CCDC141 | c.2341G>A p.D781N | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as rs757068281, COSV55382910; called by muse, mutect2, varscan2
- CD163 | c.2087C>T p.S696L | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs766660196, COSV63131903; called by muse, mutect2, varscan2
- CD1E | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 30/94 reads (32%) | catalogued as COSV63773095; called by muse, mutect2, varscan2
- CDH6 | c.1033C>T p.L345F | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.144); catalogued as COSV99421004; called by muse, mutect2, varscan2
- CEACAM21 | c.566G>A p.R189K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as rs986350876, COSV51816669; called by muse, mutect2
- CFAP221 | c.1777C>T p.H593Y | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs781138969, COSV54663275, COSV99732636; called by muse, mutect2, varscan2
- CFAP52 | c.1186G>A p.G396S | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as rs768614574, COSV100234927, COSV55349743; called by muse, mutect2, varscan2
- CFHR2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.089); catalogued as COSV100804371, COSV66380555; called by muse, mutect2, varscan2
- CHAT | c.1397G>A p.R466K | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60333555; called by muse, mutect2, varscan2
- CHSY3 | c.1987T>C p.S663P | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV59288923; called by muse, mutect2, varscan2
- CNTNAP5 | c.3826G>A p.E1276K | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.874); catalogued as rs536094106, COSV70513335; called by muse, mutect2, varscan2
- COL11A1 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV62175793, COSV62187314, COSV62198658; called by muse, mutect2, varscan2
- COL22A1 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1254786595, COSV57362072; called by muse, mutect2
- COL4A3 | c.3160G>A p.G1054R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1316595667, COSV59257727; called by muse, mutect2, varscan2
- COL9A1 | c.2630G>A p.R877Q | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.15); PolyPhen benign (0.328); catalogued as rs1408064118, COSV57884180; called by muse, mutect2, varscan2
- CPLANE2 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV65057414; called by muse, mutect2, varscan2
- CRLF1 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs751204280, COSV101135176, COSV66504117; called by muse, mutect2, varscan2
- CRY2 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV69889409; called by muse, mutect2, varscan2
- CRYZ | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV100558668, COSV61718681; called by muse, mutect2, varscan2
- CSMD2 | c.3736G>A p.G1246S | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53912851; called by muse, mutect2, varscan2
- CSMD2 | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53966022; called by muse, mutect2, varscan2
- CSNK2A1 | c.717T>G p.Y239* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as COSV53937842; called by muse, mutect2, varscan2
- CUBN | c.10312C>T p.H3438Y | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as COSV64713793, COSV64715695; called by muse, mutect2, varscan2
- CUX2 | c.4268C>T p.S1423F | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.486); catalogued as COSV55648751; called by muse, mutect2, varscan2
- CYLC2 | c.932A>T p.E311V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV66339717; called by muse, mutect2, varscan2
- DAAM1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV62839962; called by muse, varscan2
- DAB1 | c.960T>A p.S320R (on ENST00000371231; = p.S287R on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as COSV64698443; called by muse, mutect2, varscan2
- DBF4B | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as rs759337451, COSV59263996; called by muse, mutect2, varscan2
- DDX50 | c.1935G>A p.Q645= | Splice Region (SNP) | VAF 16/58 reads (28%) | catalogued as COSV65293420; called by muse, mutect2, varscan2
- DHX34 | c.1133G>T p.R378L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs903106077, COSV60898398; called by muse, mutect2, varscan2
- DLEC1 | c.4964G>A p.R1655Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.239); catalogued as rs766331966, COSV57180969; called by muse, mutect2, varscan2
- DNAH9 | c.7787C>T p.T2596M | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.746); catalogued as rs770146400, COSV52348426; called by muse, mutect2, varscan2
- DNAJC16 | c.2276C>T p.S759F | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV65435789; called by muse, mutect2, varscan2
- DOCK8 | c.5347G>A p.V1783I | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs532879343, COSV66624141; called by muse, mutect2, varscan2
- DPPA2 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as rs922189877, COSV72118023; called by muse, mutect2, varscan2
- DQX1 | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV52047251, COSV52047608; called by muse, mutect2, varscan2
- DUSP15 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.202); catalogued as COSV54068454; called by muse, mutect2, varscan2
- EBLN2 | c.616C>T p.L206F | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.961); catalogued as COSV55598120; called by muse, mutect2, varscan2
- ELFN2 | c.841C>T p.L281F | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.759); catalogued as COSV68743839; called by muse, mutect2, varscan2
- EML5 | c.2672G>A p.R891K | Missense Mutation (SNP) | VAF 97/316 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759900762, COSV61352138; called by muse, mutect2, varscan2
- EP300 | c.3641C>T p.S1214F | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV54325808, COSV54346228; called by muse, mutect2, varscan2
- EPG5 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as COSV56356288; called by muse, mutect2, varscan2
- EPYC | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.195); catalogued as rs138857092; called by muse, mutect2, varscan2
- EPYC | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 64/185 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.037); catalogued as rs770231424, COSV53802276; called by muse, mutect2, varscan2
- ERBB4 | c.2131C>T p.R711C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs267599191, COSV53505317; called by muse, mutect2, varscan2
- ERICH5 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV100582888; called by muse, mutect2, varscan2
- ERICH5 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.107); catalogued as rs1353972647, COSV100582889; called by muse, mutect2, varscan2
- ESS2 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.934); catalogued as COSV52818986; called by muse, mutect2, varscan2
- ETS1 | c.1175G>A p.G392D | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV60097939; called by muse, mutect2, varscan2
- EXOC3 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV59268801; called by muse, mutect2, varscan2
- F5 | c.4021C>T p.P1341S | Missense Mutation (SNP) | VAF 94/313 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs768912341, COSV63128760, COSV63129381; called by muse, mutect2, varscan2
- F8 | c.4499C>A p.P1500Q | Missense Mutation (SNP) | VAF 52/66 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV64279007; called by muse, mutect2, varscan2
- FAM117B | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | catalogued as rs61740247, COSV57422501; called by muse, varscan2
- FAM83G | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1485437010, COSV58762309; called by muse, mutect2, varscan2
- FARSB | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV56052752; called by muse, mutect2, varscan2
- FBN3 | c.4005A>C p.R1335S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV54473676; called by mutect2, varscan2
- FCMR | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV65569641; called by muse, mutect2, varscan2
- FLNC | c.6959G>A p.G2320E | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV57964882; called by muse, mutect2, varscan2
- FNDC3A | c.1910G>A p.R637Q (on ENST00000492622 / NM_001079673.2; = p.R581Q on NM_014923.5) | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs764785324, COSV68135085; called by muse, mutect2, varscan2
- FSHB | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV54221267; called by muse, mutect2, varscan2
- FYTTD1 | c.869C>T p.T290M | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780771845, COSV54086454; called by muse, mutect2, varscan2
- FZD9 | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as rs1166467049, COSV59994799; called by muse, mutect2, varscan2
- GAS2L3 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as COSV57156229; called by muse, mutect2, varscan2
- GCM2 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 115/307 reads (37%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.573); catalogued as COSV65276640; called by muse, mutect2, varscan2
- GDF3 | c.270T>C p.G90= | Splice Region (SNP) | VAF 24/54 reads (44%) | catalogued as rs764266672, COSV61713859; called by muse, mutect2, varscan2
- GJA8 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as COSV53790742, COSV99569770; called by muse, mutect2, varscan2
- GLI3 | c.1955C>T p.P652L | Missense Mutation (SNP) | VAF 82/188 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as rs776107503, COSV67895241; called by muse, mutect2, varscan2
- GPHN | c.1172G>A p.G391E (on ENST00000315266 / NM_001377519.1; = p.G424E on NM_020806.5) | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.378); catalogued as COSV59494108; called by muse, mutect2, varscan2
- GPR155 | c.1906C>T p.Q636* | Nonsense Mutation (SNP) | VAF 27/115 reads (23%) | catalogued as COSV55042397; called by muse, mutect2, varscan2
- GRID2 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as COSV56181101, COSV56270360; called by muse, mutect2, varscan2
- GRIN2B | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.073); catalogued as COSV74208114; called by muse, mutect2, varscan2
- GRM3 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64480047; called by muse, mutect2, varscan2
- GRM4 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs988941717, COSV65214744; called by muse, mutect2, varscan2
- GRPR | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 76/110 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66669319, COSV66670311; called by muse, mutect2, varscan2
- GTF3C3 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs757675776, COSV55834717; called by muse, mutect2, varscan2
- H1-7 | c.437G>A p.R146K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.122); catalogued as rs1046237683, COSV58603021; called by muse, mutect2, varscan2
- HAUS6 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63253117; called by muse, mutect2, varscan2
- HBG2 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100400619, COSV57964610; called by muse, mutect2, varscan2
- HCN1 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57502899; called by muse, mutect2, varscan2
- HDC | c.1901T>C p.I634T | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.015); catalogued as rs1182906549, COSV51082704; called by muse, mutect2, varscan2
- HECW1 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); catalogued as rs200226327, COSV67822658; called by muse, mutect2, varscan2
- HECW1 | c.3013G>A p.D1005N | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV67840581; called by muse, mutect2, varscan2
- HGS | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV61270448; called by muse, mutect2, varscan2
- HHLA2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as rs367817011, COSV63316232; called by muse, mutect2, varscan2
- HIPK2 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV61233008; called by muse, mutect2, varscan2
- HOXB1 | c.73C>T p.H25Y | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as COSV53318788, COSV99495765; called by muse, mutect2, varscan2
- HSPD1 | c.878T>C p.V293A | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.13); catalogued as COSV61446427; called by muse, mutect2, varscan2
- HTR1E | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59511240; called by muse, mutect2, varscan2
- HTR1F | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV60391344; called by muse, mutect2, varscan2
- HUNK | c.1330A>T p.K444* | Nonsense Mutation (SNP) | VAF 29/122 reads (24%) | catalogued as COSV54234710; called by muse, mutect2, varscan2
- IKZF2 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.36); catalogued as rs754175284, COSV59577577; called by muse, mutect2, varscan2
- IL37 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as rs145730208, COSV54492103; called by muse, mutect2, varscan2
- ING1 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.031); catalogued as COSV100312406; called by muse, mutect2, varscan2
- ING1 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.217); catalogued as rs370758745; called by muse, mutect2, varscan2
- INPP5J | c.2519C>T p.S840L (on ENST00000331075 / NM_001284285.2; = p.S472L on NM_001002837.2) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs200880716, COSV53208435; called by mutect2, varscan2
- ISLR | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1251200733, COSV51435278; called by muse, mutect2, varscan2
- JCAD | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs1328576437, COSV64761766; called by muse, mutect2, varscan2
- JMY | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV68662592; called by muse, mutect2, varscan2
- KCNH5 | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs778225685, COSV59760575, COSV59779000; called by muse, mutect2, varscan2
- KCNJ15 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.391); catalogued as COSV60812054; called by muse, mutect2, varscan2
- KCNJ6 | c.336G>A p.W112* | Nonsense Mutation (SNP) | VAF 72/268 reads (27%) | catalogued as COSV55723655; called by muse, mutect2, varscan2
- KCNK13 | c.1191G>A p.M397I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV56418007; called by muse, mutect2, varscan2
- KEL | c.600G>T p.Q200H | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV62338044; called by muse, mutect2, varscan2
- KLHDC8B | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60412862; called by muse, mutect2, varscan2
- KLHL28 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV61889429; called by muse, mutect2, varscan2
- KMT2A | c.7717C>T p.P2573S | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.01); catalogued as COSV63292795; called by muse, mutect2, varscan2
- KMT2C | c.13027del p.E4343Kfs*13 | Frame Shift Del (DEL) | VAF 27/87 reads (31%) | catalogued as COSV51489421; called by mutect2, pindel, varscan2
- KRTAP10-6 | c.171C>A p.C57* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV100555622; called by muse, mutect2, varscan2
- LAMP3 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs772205737, COSV55617127; called by muse, mutect2, varscan2
- LBHD1 | c.781G>A p.A261T (on ENST00000431002 / NM_001367940.1; = p.A235T on NM_024099.3) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.096); catalogued as rs144393003; called by muse, mutect2, varscan2
- LILRA1 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV52185337; called by muse, mutect2, varscan2
- LIPH | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56186444; called by muse, mutect2, varscan2
- LMO7 | c.1693G>A p.E565K (on ENST00000357063; = p.E295K on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.113); catalogued as COSV58549692; called by muse, mutect2, varscan2
- LMO7 | c.3970C>G p.Q1324E (on ENST00000357063; = p.Q1005E on NM_005358.5) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.044); catalogued as COSV58549713; called by muse, mutect2, varscan2
- LMX1A | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as rs538869163, COSV54216475; called by muse, mutect2, varscan2
- LPAR3 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 117/358 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV65455211; called by muse, mutect2, varscan2
- LRP12 | c.1324G>A p.G442S | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52634862; called by muse, mutect2, varscan2
- LRP4 | c.3841G>A p.G1281S | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV101066900; called by muse, mutect2, varscan2
- LRRC30 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 70/238 reads (29%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV67302372; called by muse, mutect2, varscan2
- LRRC4 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50819003; called by muse, mutect2
- MACF1 | c.3368C>T p.P1123L | Missense Mutation (SNP) | VAF 41/111 reads (37%) | catalogued as COSV58403784; called by muse, mutect2, varscan2
- MAFB | c.494A>G p.H165R | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.61); catalogued as COSV64827143; called by muse, mutect2, varscan2
- MAFB | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64826474, COSV64827148; called by muse, mutect2
- MAP3K14 | c.1862C>T p.S621F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV60924364; called by muse, mutect2, varscan2
- MAP3K9 | c.2980C>T p.R994W (on ENST00000554752 / NM_001284230.1; = p.R1008W on NM_033141.4) | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs762288591, COSV67122641; called by muse, mutect2, varscan2
- MAST1 | c.1864T>C p.S622P | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs776147023, COSV52255542; called by muse, mutect2, varscan2
- MATR3 | c.2487A>T p.K829N | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV63080294; called by muse, mutect2, varscan2
- MCF2 | c.2342G>A p.G781D | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV58495443; called by muse, mutect2, varscan2
- MDN1 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.668); catalogued as COSV65530696; called by muse, mutect2, varscan2
- MECOM | c.20C>T p.P7L (on ENST00000468789 / NM_001105078.4; = p.P195L on NM_004991.4) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1488607871, COSV52975688; called by muse, mutect2, varscan2
- MED16 | c.490T>C p.F164L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV54131873; called by muse, mutect2, varscan2
- MGAM | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs779098977, COSV71884967; called by muse, mutect2, varscan2
- MIB2 | c.1621C>G p.Q541E | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.99); catalogued as COSV61543484; called by muse, mutect2
- MKX | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.691); catalogued as COSV65393369; called by muse, mutect2, varscan2
- MMP13 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs1555016840, COSV52825758; called by muse, mutect2, varscan2
- MRC2 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV57644858; called by muse, mutect2, varscan2
- MSTN | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53622010; called by muse, mutect2, varscan2
- MUC16 | c.37810G>A p.E12604K | Missense Mutation (SNP) | VAF 44/67 reads (66%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs749277251, COSV101197836, COSV67466588; called by muse, mutect2, varscan2
- MUC16 | c.33248C>T p.S11083L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.051); catalogued as COSV67495690; called by muse, mutect2, varscan2
- MUC2 | c.1969G>A p.D657N | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as rs1420100961; called by muse, mutect2
- MYH2 | c.4894G>A p.E1632K | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55448959; called by muse, mutect2, varscan2
- NAALAD2 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs761176623, COSV58958461; called by muse, mutect2, varscan2
- NADK | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1029258396, COSV58274155; called by muse, mutect2, varscan2
- NADK | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100411087; called by muse, mutect2, varscan2
- NBEAL1 | c.6507T>G p.N2169K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68916082; called by muse, mutect2, varscan2
- NDFIP1 | c.134T>A p.I45N | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV54076481; called by muse, mutect2, varscan2
- NDRG2 | c.493G>A p.G165S (on ENST00000298687 / NM_001354570.1; = p.G151S on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV53873682; called by muse, mutect2, varscan2
- NEK5 | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.171); catalogued as COSV62881899, COSV62882074; called by muse, mutect2, varscan2
- NETO1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as rs1395330447, COSV55006087, COSV55012049; called by muse, mutect2, varscan2
- NETO2 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.548); catalogued as COSV57451814; called by muse, mutect2, varscan2
- NEXMIF | c.3409C>T p.Q1137* | Nonsense Mutation (SNP) | VAF 44/60 reads (73%) | catalogued as COSV50126694; called by muse, mutect2, varscan2
- NLRP2 | c.2977C>T p.P993S | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as COSV54760667; called by muse, mutect2, varscan2
- NLRP2 | c.2978C>T p.P993L | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.166); catalogued as COSV54755873; called by muse, mutect2, varscan2
- NOL4 | c.1406T>G p.M469R | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV52363020; called by muse, mutect2, varscan2
- NOTCH1 | c.6665C>T p.P2222L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs779125725, COSV53078158; called by muse, mutect2, varscan2
- NOTCH1 | c.6664C>T p.P2222S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV53045994; called by muse, mutect2, varscan2
- NOTCH1 | c.4366G>A p.E1456K | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV53097058; called by muse, mutect2, varscan2
- NPAP1 | c.22T>C p.F8L | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV61511594; called by muse, mutect2, varscan2
- NPC1 | c.2344C>T p.L782F | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV52583881; called by muse, mutect2, varscan2
- NPDC1 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58665455; called by muse, mutect2, varscan2
- NRXN3 | c.388G>C p.D130H (on ENST00000557594 / NM_001272020.2; = p.D762H on NM_004796.6) | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55351143, COSV55357235; called by muse, mutect2, varscan2
- NTNG1 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.097); catalogued as COSV53989704; called by muse, mutect2, varscan2
- NUFIP1 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as COSV63151525, COSV63152121; called by muse, mutect2, varscan2
- NYAP2 | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 97/235 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.221); catalogued as rs1401726033, COSV56017071; called by muse, mutect2, varscan2
- OR10H4 | c.527A>C p.H176P | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); catalogued as COSV59063114; called by muse, mutect2, varscan2
- OR1L8 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV59185762; called by muse, mutect2, varscan2
- OR2M3 | c.914T>C p.L305S | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV71759302; called by muse, mutect2, varscan2
- OR4N2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 124/441 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs866280852, COSV60050102; called by muse, mutect2
- OR52E6 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs868025221, COSV61432022, COSV61433561; called by muse, mutect2, varscan2
- OR56A3 | c.28T>A p.S10T | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV61570135; called by muse, mutect2, varscan2
- OR5AR1 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV57255437; called by muse, mutect2, varscan2
- OR5H1 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 119/358 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.078); catalogued as COSV100641751, COSV100641786; called by muse, mutect2, varscan2
- OR5V1 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV65827182; called by muse, mutect2, varscan2
- OR7G3 | c.854T>G p.L285R | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV59641147; called by muse, mutect2, varscan2
- OTUD4 | c.329C>T p.S110F (on ENST00000447906 / NM_001366057.1; = p.S45F on NM_017493.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV56850269; called by muse, mutect2, varscan2
- PAX1 | c.521C>T p.T174I | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68273512; called by muse, mutect2, varscan2
- PCARE | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); catalogued as COSV100527918, COSV59055781; called by muse, mutect2, varscan2
- PCARE | c.699G>T p.L233F | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100527919; called by muse, mutect2, varscan2
- PCDHA8 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as rs782217721, COSV65334558; called by muse, mutect2, varscan2
- PCDHB4 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52027217; called by muse, mutect2, varscan2
- PCDHGB4 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53930736; called by muse, mutect2, varscan2
- PCLO | c.2146C>T p.P716S | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV61668241; called by muse, mutect2, varscan2
- PCSK1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs868205015, COSV60737689; called by muse, mutect2, varscan2
- PCSK5 | c.224A>C p.Y75S | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as COSV65096947; called by muse, mutect2, varscan2
- PCSK5 | c.3574G>A p.G1192R | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs757755652, COSV101377569, COSV70452923; called by muse, mutect2, varscan2
- PDE1B | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.677); catalogued as rs112699956, COSV54496508; called by muse, mutect2, varscan2
- PDZD4 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as rs1557077933, COSV51251943; called by muse, mutect2, varscan2
- PHLDB2 | c.2212G>A p.E738K (on ENST00000393925 / NM_001134439.2; = p.E695K on NM_145753.2) | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV67316366; called by muse, mutect2, varscan2
- PIGS | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV52026643; called by muse, mutect2, varscan2
- PIWIL1 | c.2398A>C p.N800H | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.663); catalogued as rs1398288809, COSV55352267; called by muse, mutect2, varscan2
- PKHD1L1 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); catalogued as rs1159235756, COSV65742447; called by muse, mutect2, varscan2
- PKLR | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 127/189 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV61361255; called by muse, mutect2, varscan2
- PLCB3 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs267603096, COSV54192465; called by muse, mutect2, varscan2
- PLEKHH2 | c.2964T>G p.N988K | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56761615; called by muse, mutect2, varscan2
- POLI | c.2095G>C p.D699H | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.365); catalogued as rs1487099441, COSV54191793; called by muse, mutect2, varscan2
- POTEM | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 135/558 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as rs1407296400; called by muse, varscan2
- PRAMEF2 | c.627G>T p.E209D | Missense Mutation (SNP) | VAF 77/239 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV53575313, COSV53579531; called by muse, mutect2, varscan2
- PRDM16 | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV54609457; called by muse, mutect2, varscan2
- PREX2 | c.2168A>C p.N723T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55800052; called by muse, mutect2, varscan2
- PRM2 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | PolyPhen possibly damaging (0.849); catalogued as rs1320977090, COSV54114029; called by muse, mutect2, varscan2
- PROX1 | c.2180C>T p.S727F | Missense Mutation (SNP) | VAF 59/92 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54779452, COSV54784051; called by muse, mutect2, varscan2
- PSG2 | c.907G>T p.V303F | Missense Mutation (SNP) | VAF 104/262 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV61546625; called by muse, mutect2, varscan2
- PTF1A | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 99/306 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV64735451; called by muse, mutect2
- PTH1R | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs772490281, COSV57315608, COSV57317957; called by muse, mutect2, varscan2
- PTPRC | c.2402A>G p.N801S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61420853; called by muse, mutect2, varscan2
- RASA2 | c.2288C>T p.S763F | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1051473622, COSV53946581; called by muse, mutect2, varscan2
- RASSF6 | c.448C>T p.P150S (on ENST00000342081 / NM_201431.2; = p.P118S on NM_177532.5) | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV56719433, COSV56721330; called by muse, mutect2, varscan2
- RET | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); catalogued as COSV60708712; called by muse, varscan2
- RIOX1 | c.1600G>T p.E534* | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | catalogued as COSV58374852; called by muse, mutect2, varscan2
- RNF213 | c.2216C>T p.S739F | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100174033; called by muse, mutect2, varscan2
- RNF43 | c.1802C>A p.S601Y | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.188); catalogued as COSV101348375, COSV68458156; called by muse, mutect2, varscan2
- ROS1 | c.1972G>A p.G658S | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.976); catalogued as rs1025709504, COSV63861934; called by muse, mutect2, varscan2
- RPL22 | c.44dup p.K16Efs*9 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | catalogued as rs759765382; called by mutect2, varscan2
- RPTN | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 426/2152 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as COSV60169331; called by muse, mutect2, varscan2
- RRM2 | c.945G>A p.M315I | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.105); catalogued as COSV58815971; called by muse, mutect2, varscan2
- RWDD2B | c.744G>A p.W248* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV54501575; called by muse, mutect2, varscan2
- SALL1 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866692687, COSV51753059; called by muse, mutect2, varscan2
- SBF1 | c.4928C>T p.P1643L | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.083); catalogued as rs777083733, COSV62370542; called by muse, mutect2, varscan2
- SCN11A | c.5035C>T p.R1679C | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs143537709, COSV56566354, COSV56579756; called by muse, mutect2, varscan2
- SCN1B | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV52895983; called by muse, mutect2, varscan2
- SEZ6L | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.427); catalogued as rs760398959, COSV50690159; called by muse, mutect2, varscan2
- SGIP1 | c.1444-2A>G p.X482_splice | Splice Site (SNP) | VAF 53/186 reads (28%) | catalogued as rs1220107093; called by muse, mutect2, varscan2
- SHC3 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs929098639, COSV65447398; called by muse, mutect2, varscan2
- SIAH2 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1461624320, COSV57261549, COSV57261935; called by muse, mutect2, varscan2
- SIDT1 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV53507635; called by muse, mutect2, varscan2
- SIN3A | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV64585130; called by muse, mutect2, varscan2
- SIPA1L3 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55924711; called by muse, mutect2, varscan2
- SLC25A10 | c.715C>T p.H239Y | Missense Mutation (SNP) | VAF 122/378 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.201); catalogued as COSV58972034; called by muse, mutect2, varscan2
- SLC25A41 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51197719; called by muse, mutect2, varscan2
- SLC2A10 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs772782894, COSV63716073; called by muse, mutect2, varscan2
- SLC35C1 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as COSV58480959; called by muse, mutect2, varscan2
- SLC4A5 | c.1714G>A p.G572R | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1305879566, COSV61033221; called by muse, mutect2, varscan2
- SLC9A4 | c.1780G>A p.D594N | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV54839573; called by muse, mutect2, varscan2
- SLITRK3 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV53846649; called by muse, mutect2, varscan2
- SOX10 | c.697+1G>A p.X233_splice | Splice Site (SNP) | VAF 16/65 reads (25%) | catalogued as COSV100704213; called by muse, mutect2, varscan2
- SOX10 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.323); catalogued as COSV100704215; called by muse, mutect2, varscan2
- SPATA31E1 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.991); catalogued as COSV57795557; called by muse, mutect2, varscan2
- SPEF2 | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs938738108, COSV61553982; called by muse, mutect2, varscan2
- STRA6 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as rs758321198, COSV51435284; called by muse, mutect2
- SVEP1 | c.2882C>T p.P961L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs776291399, COSV57041725; called by muse, mutect2, varscan2
- SZT2 | c.9659C>T p.P3220L (on ENST00000634258 / NM_001365999.1; = p.P3163L on NM_015284.4) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV65095501; called by muse, mutect2, varscan2
- TAAR5 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as rs1054812130, COSV57799930; called by muse, mutect2, varscan2
- TBC1D21 | c.992del p.L331* | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as COSV100311454, COSV55996111; called by mutect2, pindel, varscan2
- TDG | c.280A>T p.K94* | Nonsense Mutation (SNP) | VAF 9/106 reads (8%) | catalogued as COSV57168730; called by muse, mutect2
- TENM2 | c.731G>A p.S244N (on ENST00000518659 / NM_001122679.2; = p.S53N on NM_001080428.3) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.01); catalogued as COSV69135314; called by muse, mutect2
- TEP1 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377196077; called by muse, mutect2, varscan2
- TEX14 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53619667, COSV99543623; called by muse, mutect2, varscan2
- TGIF2LX | c.239A>C p.E80A | Missense Mutation (SNP) | VAF 74/107 reads (69%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV52215273; called by muse, mutect2, varscan2
- THAP12 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52613255; called by muse, mutect2, varscan2
- THBS4 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV63471043; called by muse, mutect2, varscan2
- TIGD6 | c.1506G>A p.M502I | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV57061819; called by muse, mutect2, varscan2
- TMEM176A | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50241566, COSV50245377; called by muse, mutect2, varscan2
- TMEM200A | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs763623830, COSV51660044; called by muse, mutect2, varscan2
- TMEM208 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV50770775; called by mutect2, varscan2
- TMIGD2 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 64/91 reads (70%) | SIFT tolerated (0.18); PolyPhen benign (0.153); catalogued as COSV56668888; called by muse, mutect2, varscan2
- TNK2 | c.2177C>T p.A726V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1265493204, COSV57376287; called by muse, mutect2, varscan2
- TOR1AIP2 | c.646T>G p.W216G | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV62627278; called by muse, mutect2, varscan2
- TOX | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as COSV63850876; called by muse, mutect2, varscan2
- TRBV30 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs926792847; called by muse, mutect2, varscan2
- TRBV4-1 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 114/264 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.498); catalogued as rs752240970; called by muse, mutect2, varscan2
- TRIM24 | c.2390C>T p.S797F (on ENST00000343526 / NM_015905.3; = p.S763F on NM_003852.4) | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV58978509; called by muse, mutect2, varscan2
- TRIM27 | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 54/176 reads (31%) | catalogued as COSV65874108; called by muse, mutect2, varscan2
- TRPS1 | c.1056A>C p.Q352H (on ENST00000220888 / NM_001330599.2; = p.Q365H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.993); catalogued as COSV55263274; called by muse, mutect2, varscan2
- TRPV3 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV56796076; called by muse, mutect2, varscan2
- TSHR | c.1391G>A p.G464E | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53332310; called by muse, mutect2, varscan2
- TSHZ1 | c.1952A>G p.N651S (on ENST00000580243 / NM_001308210.2; = p.N606S on NM_005786.6) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1018105040, COSV59013625, COSV59018213; called by muse, mutect2, varscan2
- TTLL4 | c.169A>G p.K57E | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV51439684; called by muse, mutect2, varscan2
- TTLL5 | c.1646T>C p.L549P | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54044568; called by muse, mutect2, varscan2
- TTN | c.50197G>A p.E16733K (on ENST00000591111; = p.E9309K on NM_003319.4) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | PolyPhen possibly damaging (0.52); catalogued as COSV100618073, COSV100632288; called by muse, mutect2, varscan2
- TTN | c.33175G>A p.E11059K (on ENST00000591111; = p.E10132K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/138 reads (38%) | PolyPhen benign (0.406); catalogued as COSV59983998; called by muse, mutect2, varscan2
- TTN | c.5132C>T p.S1711F (on ENST00000591111; = p.S1665F on NM_003319.4) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | PolyPhen probably damaging (0.998); catalogued as rs397517641, COSV59928668; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGT1A8 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV65086306; called by muse, mutect2, varscan2
- UGT2B10 | c.1064G>A p.W355* | Nonsense Mutation (SNP) | VAF 43/81 reads (53%) | catalogued as COSV55323814, COSV99608480; called by muse, mutect2, varscan2
- UPP1 | c.688A>G p.K230E | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57978695; called by muse, mutect2, varscan2
- UPP2 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV50046702, COSV50049677; called by muse, mutect2, varscan2
- VWA2 | c.1624G>A p.V542I | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV53911537; called by muse, mutect2, varscan2
- WDR93 | c.1620T>A p.F540L | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV51535578; called by muse, mutect2, varscan2
- WNT2 | c.215G>A p.W72* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as COSV55414023; called by muse, mutect2, varscan2
- ZAN | c.2914C>T p.P972S | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.082); catalogued as rs1485201242, COSV100770467; called by muse, varscan2
- ZAN | c.2915C>T p.P972L | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV100770471; called by muse, varscan2
- ZC3HAV1 | c.2615C>T p.S872L | Missense Mutation (SNP) | VAF 100/202 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141924548; called by muse, mutect2, varscan2
- ZFP42 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs200711766, COSV58816789; called by muse, mutect2, varscan2
- ZHX2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs967639977, COSV58717213; called by muse, mutect2, varscan2
- ZMYM6 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 27/110 reads (25%) | catalogued as COSV58185607; called by muse, mutect2, varscan2
- ZNF154 | c.965T>C p.V322A | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV70744820; called by muse, mutect2, varscan2
- ZNF208 | c.3028T>C p.F1010L | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV68112848; called by muse, mutect2, varscan2
- ZNF251 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs756744977, COSV52958414; called by muse, mutect2, varscan2
- ZNF43 | c.1601G>T p.G534V | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV61686139; called by muse, mutect2, varscan2
- ZNF568 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV61742430; called by muse, mutect2, varscan2
- ZNF804A | c.3362C>T p.T1121I | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs754516369, COSV56472421, COSV99043238; called by muse, mutect2, varscan2
- ZNF831 | c.3340C>T p.P1114S | Missense Mutation (SNP) | VAF 61/97 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as COSV64045552; called by muse, mutect2, varscan2
- BRSK1 | c.817dup p.R273Kfs*70 | Frame Shift Ins (INS) | VAF 6/18 reads (33%) | called by mutect2, pindel, varscan2
- CDK17 | c.874-1_884del p.X292_splice | Splice Site (DEL) | VAF 13/61 reads (21%) | called by mutect2, varscan2
- DNMT3A | c.2578dup p.W860Lfs*4 | Frame Shift Ins (INS) | VAF 18/36 reads (50%) | called by mutect2, pindel, varscan2
- FAXC | c.373dup p.Y125Lfs*6 | Frame Shift Ins (INS) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- KRTAP10-4 | c.171C>A p.C57* | Nonsense Mutation (SNP) | VAF 24/218 reads (11%) | called by muse, mutect2
- A4GALT | c.1032G>A p.T344= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs781151702, COSV50746609; called by muse, mutect2, varscan2
- ABCA9 | c.4080C>T p.P1360= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as rs763480191, COSV60631455; called by muse, mutect2, varscan2
- ABI3 | c.969G>A p.K323= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs779153352, COSV56799277; called by muse, mutect2, varscan2
- ACKR1 | c.166C>T p.L56= | Silent (SNP) | VAF 50/115 reads (43%) | catalogued as COSV63674690; called by muse, mutect2, varscan2
- ADCY4 | c.2772C>T p.I924= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as COSV60257852, COSV60258355; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.348G>A p.R116= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as COSV58447351; called by muse, mutect2, varscan2
- AGBL2 | c.1596C>T p.F532= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV54095515; called by muse, mutect2, varscan2
- AP1M1 | c.1266C>T p.T422= | Silent (SNP) | VAF 31/47 reads (66%) | catalogued as COSV52229235; called by muse, mutect2, varscan2
- APMAP | c.312C>T p.S104= | Silent (SNP) | VAF 50/88 reads (57%) | catalogued as COSV54177145; called by muse, mutect2, varscan2
- ARMC12 | c.171A>G p.A57= (on ENST00000373866 / NM_001286574.2; = p.A84= on NM_145028.5) | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as COSV55361842; called by muse, mutect2, varscan2
- ARSF | c.1365C>T p.A455= | Silent (SNP) | VAF 45/78 reads (58%) | catalogued as rs144086355, COSV63839404; called by muse, mutect2, varscan2
- ATP13A5 | c.2808C>T p.L936= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV60875843; called by muse, mutect2, varscan2
- ATP13A5 | c.1308C>T p.I436= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs753073040, COSV60868144, COSV60875853; called by muse, mutect2, varscan2
- B3GNT3 | c.1118G>A p.*373= | Silent (SNP) | VAF 34/55 reads (62%) | catalogued as COSV57954014; called by muse, mutect2, varscan2
- BEGAIN | c.708G>A p.P236= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs572759912, COSV62070276; called by muse, mutect2, varscan2
- BTN1A1 | c.415C>T p.L139= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs1325545112, COSV55069741; called by muse, mutect2, varscan2
- C17orf58 | c.111G>A p.R37= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as COSV57817224; called by muse, mutect2, varscan2
- C1QC | c.477C>T p.T159= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV65890101; called by muse, mutect2, varscan2
- CACNA1H | c.4659C>T p.V1553= | Silent (SNP) | VAF 60/204 reads (29%) | catalogued as rs372465474; called by muse, mutect2, varscan2
- CACNA2D1 | c.618G>A p.Q206= | Silent (SNP) | VAF 45/106 reads (42%) | catalogued as COSV62392107; called by muse, mutect2, varscan2
- CACNA2D3 | c.429G>A p.G143= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs267599904, COSV55518510; called by muse, mutect2, varscan2
- CACNG6 | c.525C>T p.A175= | Silent (SNP) | VAF 60/149 reads (40%) | catalogued as rs760117769, COSV53168472; called by muse, mutect2, varscan2
- CD1B | c.216T>C p.S72= | Silent (SNP) | VAF 68/445 reads (15%) | catalogued as rs375291026; called by muse, mutect2, varscan2
- CD33 | c.525G>A p.P175= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as rs571230664, COSV51803810; called by muse, mutect2, varscan2
- CD8A | c.603T>G p.V201= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV52159580; called by muse, mutect2
- CDH2 | c.1671T>C p.A557= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs1205109742, COSV52297014; called by muse, mutect2, varscan2
- CDH6 | c.1032C>T p.T344= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV54063727; called by muse, mutect2, varscan2
- CEACAM4 | c.270C>T p.I90= | Silent (SNP) | VAF 33/178 reads (19%) | catalogued as COSV55733103; called by muse, mutect2, varscan2
- CLEC18B | c.1320C>T p.I440= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs753212328, COSV60578959; called by muse, mutect2, varscan2
- CLEC4E | c.378C>T p.F126= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV55226953; called by muse, mutect2, varscan2
- CLSTN1 | c.2502G>A p.P834= (on ENST00000377298 / NM_001009566.3; = p.P824= on NM_014944.4) | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as rs373408826; called by muse, mutect2, varscan2
- COL4A6 | c.1659C>T p.I553= | Silent (SNP) | VAF 60/86 reads (70%) | catalogued as COSV57874450, COSV57878910; called by muse, mutect2, varscan2
- CTNND2 | c.1191C>T p.A397= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV58930120; called by muse, mutect2
- CYFIP2 | c.2589C>T p.I863= (on ENST00000616178 / NM_001291722.2; = p.I838= on NM_014376.4) | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV56638176; called by muse, mutect2, varscan2
- CYP4A11 | c.1176G>A p.E392= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs1298589176, COSV60225799; called by muse, mutect2, varscan2
- CYP4X1 | c.984C>T p.I328= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as rs991608173, COSV100903316, COSV64150016; called by muse, mutect2, varscan2
- DNAH9 | c.7038G>A p.Q2346= | Silent (SNP) | VAF 58/99 reads (59%) | catalogued as COSV52377937; called by muse, mutect2, varscan2
- DNER | c.1734C>T p.C578= | Silent (SNP) | VAF 54/126 reads (43%) | catalogued as rs376723054; called by muse, mutect2, varscan2
- DTX1 | c.1467C>T p.F489= | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as COSV55655043; called by muse, mutect2, varscan2
- DZIP3 | c.1440C>T p.F480= | Silent (SNP) | VAF 43/134 reads (32%) | catalogued as rs1430703900, COSV64314039; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2586C>T p.F862= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV62571092; called by muse, mutect2, varscan2
- ELOVL2 | c.639C>T p.F213= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as rs757569244, COSV61156178; called by muse, mutect2, varscan2
- ELP3 | c.795G>A p.K265= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV56461662; called by muse, mutect2, varscan2
- EPS8L1 | c.184T>C p.L62= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs756415571, COSV52386510; called by muse, mutect2, varscan2
- FAM13B | c.1599C>T p.F533= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as rs771876325, COSV50374803; called by muse, mutect2, varscan2
- FBXO24 | c.429G>A p.K143= (on ENST00000241071 / NM_033506.3; = p.K181= on NM_012172.5) | Silent (SNP) | VAF 73/173 reads (42%) | catalogued as rs142866619; called by muse, mutect2, varscan2
- FSIP2 | c.18438T>C p.V6146= | Silent (SNP) | VAF 45/89 reads (51%) | catalogued as COSV58100442; called by muse, mutect2, varscan2
- FZD9 | c.591G>A p.E197= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV60671433; called by muse, mutect2, varscan2
- G6PC | c.948C>T p.S316= | Silent (SNP) | VAF 64/224 reads (29%) | catalogued as rs137978566, COSV53832815; called by muse, mutect2, varscan2
- GALNT2 | c.558C>T p.L186= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as COSV64197688; called by muse, mutect2, varscan2
- GBP2 | c.948C>T p.A316= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as COSV65070511; called by muse, mutect2, varscan2
- GIMAP8 | c.555C>T p.L185= | Silent (SNP) | VAF 56/205 reads (27%) | catalogued as COSV56234276; called by muse, mutect2, varscan2
- GLRX3 | c.291C>T p.I97= | Silent (SNP) | VAF 25/39 reads (64%) | catalogued as rs748966258, COSV58694626; called by muse, mutect2, varscan2
- GP6 | c.87C>T p.S29= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV59979806; called by muse, mutect2, varscan2
- GRIA2 | c.1329G>A p.E443= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV52407040; called by muse, mutect2, varscan2
- GRM3 | c.681C>T p.I227= | Silent (SNP) | VAF 54/125 reads (43%) | catalogued as COSV64469711; called by muse, mutect2, varscan2
- HECW2 | c.1803C>T p.L601= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs754616780, COSV53674092; called by muse, mutect2, varscan2
- IGHG2 | c.648C>T p.S216= | Silent (SNP) | VAF 85/265 reads (32%) | catalogued as rs1316543961; called by muse, mutect2, varscan2
- KCNK10 | c.627C>T p.I209= | Silent (SNP) | VAF 62/165 reads (38%) | catalogued as COSV56651863; called by muse, mutect2, varscan2
- KCNN3 | c.1254C>T p.I418= | Silent (SNP) | VAF 26/140 reads (19%) | catalogued as rs1489445780, COSV55227455; called by muse, mutect2, varscan2
- LAMA3 | c.9801G>A p.Q3267= (on ENST00000313654 / NM_198129.4; = p.Q1658= on NM_000227.6) | Silent (SNP) | VAF 42/119 reads (35%) | catalogued as rs1461089698, COSV52543805; called by muse, mutect2, varscan2
- LINGO4 | c.1629C>T p.F543= | Silent (SNP) | VAF 62/547 reads (11%) | catalogued as COSV63216729; called by muse, mutect2, varscan2
- LRP2 | c.2124G>A p.Q708= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV55575781; called by muse, mutect2, varscan2
- MAP3K13 | c.1635G>A p.Q545= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV53998157; called by muse, mutect2, varscan2
- MCM3 | c.1128C>T p.I376= (on ENST00000229854 / NM_001366374.2; = p.I366= on NM_002388.6 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV57719577; called by muse, mutect2, varscan2
- MKX | c.693G>A p.L231= | Silent (SNP) | VAF 49/146 reads (34%) | catalogued as rs760315971, COSV65392001; called by muse, mutect2, varscan2
- MLIP | c.165C>T p.F55= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV51426588; called by muse, mutect2, varscan2
- MPV17L | c.465C>T p.V155= (on ENST00000396385 / NM_001128423.2; = p.L132= on NM_173803.4) | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV55009192; called by muse, mutect2, varscan2
- MTUS2 | c.1386G>A p.G462= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV70923101; called by muse, mutect2, varscan2
- MXRA5 | c.3459G>A p.G1153= | Silent (SNP) | VAF 44/65 reads (68%) | catalogued as COSV54251525; called by muse, mutect2, varscan2
- MYH1 | c.5403G>A p.L1801= | Silent (SNP) | VAF 79/129 reads (61%) | catalogued as rs762547535, COSV56857601; called by muse, mutect2, varscan2
- MYO3A | c.249G>A p.G83= | Silent (SNP) | VAF 56/166 reads (34%) | catalogued as COSV56341743; called by muse, mutect2, varscan2
- MYOM3 | c.861C>T p.P287= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV58401337; called by muse, mutect2, varscan2
- NEK11 | c.1677C>T p.F559= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV67286187; called by muse, mutect2, varscan2
- NEXMIF | c.3157C>T p.L1053= | Silent (SNP) | VAF 43/68 reads (63%) | catalogued as COSV50127161, COSV99280969; called by muse, mutect2, varscan2
- NLRP7 | c.1317G>A p.G439= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV60182243; called by muse, varscan2
- NPAS4 | c.1515C>T p.T505= | Silent (SNP) | VAF 121/297 reads (41%) | catalogued as COSV100215291, COSV60652922; called by muse, mutect2, varscan2
- NXF1 | c.792C>T p.I264= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV53676855; called by muse, mutect2, varscan2
- OR1L4 | c.327G>A p.G109= | Silent (SNP) | VAF 62/139 reads (45%) | catalogued as COSV52340508; called by muse, mutect2, varscan2
- OR4C16 | c.66G>A p.K22= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as rs780850295, COSV58942099, COSV58943641; called by muse, mutect2, varscan2
- OR51I1 | c.900G>A p.E300= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as COSV66507179, COSV66509328; called by muse, mutect2, varscan2
- OR52J3 | c.213T>A p.I71= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV66747833; called by muse, mutect2, varscan2
- OR7G3 | c.123G>A p.G41= | Silent (SNP) | VAF 65/110 reads (59%) | catalogued as COSV59640249; called by muse, mutect2, varscan2
- P2RX7 | c.507C>T p.P169= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs1451461795, COSV55857845; called by muse, mutect2, varscan2
- PALD1 | c.1599G>A p.T533= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs760266389; called by muse, mutect2
- PDCD11 | c.1350C>T p.I450= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs748675249, COSV63934064; called by muse, mutect2, varscan2
- PGC | c.126C>T p.F42= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV63122093; called by muse, mutect2, varscan2
- PLA2R1 | c.3477C>T p.S1159= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as COSV51777325, COSV51787135; called by muse, mutect2, varscan2
- PLEKHG2 | c.3369C>T p.I1123= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as COSV52690236; called by muse, mutect2, varscan2
- POU6F2 | c.390G>A p.Q130= | Silent (SNP) | VAF 49/197 reads (25%) | catalogued as COSV68882968; called by muse, mutect2, varscan2
- PPP1R12C | c.691C>T p.L231= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV54740683; called by muse, mutect2, varscan2
- PRAMEF12 | c.786C>T p.F262= | Silent (SNP) | VAF 37/165 reads (22%) | catalogued as COSV63216763; called by muse, mutect2, varscan2
- PRAMEF8 | c.954C>T p.I318= | Silent (SNP) | VAF 48/177 reads (27%) | called by muse, mutect2, varscan2
- PRKCH | c.1219C>T p.L407= | Silent (SNP) | VAF 83/238 reads (35%) | catalogued as COSV60652678; called by muse, mutect2, varscan2
- PTPRG | c.444G>A p.V148= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as rs140851159; called by muse, mutect2, varscan2
- RAD54B | c.1581C>T p.I527= | Silent (SNP) | VAF 74/165 reads (45%) | catalogued as rs144225041, COSV60255014; called by muse, mutect2, varscan2
- RFX4 | c.645T>C p.T215= (on ENST00000392842 / NM_213594.3; = p.T121= on NM_032491.6) | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV57581759; called by muse, mutect2, varscan2
- RHPN2 | c.237C>T p.F79= | Silent (SNP) | VAF 53/131 reads (40%) | catalogued as rs760505643, COSV54279152; called by muse, mutect2, varscan2
- RLF | c.4890T>G p.G1630= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV65653280; called by muse, mutect2, varscan2
- RNF43 | c.1803C>T p.S601= | Silent (SNP) | VAF 39/151 reads (26%) | catalogued as COSV101348564; called by muse, mutect2, varscan2
- RPRD2 | c.3993C>T p.L1331= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs757123044, COSV64823451; called by muse, mutect2, varscan2
- RSPO1 | c.606G>A p.R202= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs1323085131, COSV62975377; called by muse, mutect2, varscan2
- RYR1 | c.9616C>T p.L3206= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV62111477; called by muse, mutect2
- SAMD9L | c.327G>A p.K109= | Silent (SNP) | VAF 56/166 reads (34%) | catalogued as rs1442622829, COSV59085495; called by muse, mutect2, varscan2
- SDHAF2 | c.162A>G p.P54= | Silent (SNP) | VAF 29/158 reads (18%) | catalogued as rs1271667562, COSV57099428; called by muse, mutect2, varscan2
- SDK2 | c.3786G>A p.Q1262= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV66197555; called by muse, mutect2, varscan2
- SEC14L3 | c.612C>T p.L204= | Silent (SNP) | VAF 57/138 reads (41%) | catalogued as COSV53181694; called by muse, mutect2, varscan2
- SLC12A5 | c.2073G>A p.K691= (on ENST00000454036 / NM_001134771.2; = p.K668= on NM_020708.5) | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV54789715, COSV99715965; called by muse, mutect2, varscan2
- SLC13A2 | c.1347C>T p.T449= | Silent (SNP) | VAF 48/117 reads (41%) | catalogued as COSV58992949; called by muse, mutect2, varscan2
- SLC44A5 | c.1365C>T p.T455= | Silent (SNP) | VAF 59/135 reads (44%) | catalogued as COSV63775257; called by muse, mutect2, varscan2
- SLC6A20 | c.1659C>T p.A553= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs1254837189, COSV62072879; called by muse, mutect2, varscan2
- SLITRK1 | c.1707C>T p.F569= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV65677738; called by muse, mutect2, varscan2
- SPTA1 | c.207C>T p.I69= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV63754970, COSV63759976; called by muse, mutect2, varscan2
- SPTB | c.132G>A p.R44= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as COSV67635182; called by muse, mutect2, varscan2
- STAB1 | c.3831G>A p.R1277= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV58741765, COSV58743427, COSV58744838; called by muse, mutect2, varscan2
- SVEP1 | c.7155C>T p.P2385= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV52844386; called by muse, mutect2, varscan2
- TACC3 | c.2346C>T p.I782= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs373593258, COSV57608170; called by muse, mutect2, varscan2
- TAS2R38 | c.753C>T p.S251= | Silent (SNP) | VAF 46/143 reads (32%) | catalogued as COSV71886120; called by muse, mutect2, varscan2
- TENM3 | c.636G>A p.R212= | Silent (SNP) | VAF 51/103 reads (50%) | catalogued as COSV69304151; called by muse, mutect2, varscan2
- TEX35 | c.33A>T p.T11= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV51109010; called by muse, mutect2, varscan2
- TLR9 | c.585C>T p.L195= | Silent (SNP) | VAF 39/102 reads (38%) | catalogued as COSV59727657; called by muse, mutect2, varscan2
- TMEM215 | c.615C>T p.I205= | Silent (SNP) | VAF 44/97 reads (45%) | catalogued as rs1429165040, COSV61363165; called by muse, mutect2, varscan2
- TNKS | c.2865C>T p.A955= | Silent (SNP) | VAF 74/203 reads (36%) | catalogued as rs1256368931, COSV60066725; called by muse, mutect2, varscan2
- TRIM36 | c.2007C>T p.F669= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs1350976753, COSV56693508; called by muse, mutect2, varscan2
- TTBK2 | c.2154G>A p.E718= | Silent (SNP) | VAF 62/196 reads (32%) | catalogued as COSV51181062; called by muse, mutect2, varscan2
- TTN | c.65025C>T p.I21675= (on ENST00000591111; = p.I14251= on NM_003319.4) | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV60363445; called by muse, mutect2, varscan2
- UBE2Z | c.1047T>C p.H349= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV51727887; called by muse, mutect2, varscan2
- USP21 | c.505C>T p.L169= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV57091406; called by muse, mutect2, varscan2
- USP40 | c.2793C>T p.F931= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV52488792; called by muse, mutect2, varscan2
- XRCC5 | c.1503C>T p.P501= | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as COSV67538128; called by muse, mutect2, varscan2
- ZNF626 | c.963C>T p.A321= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as COSV74130988; called by muse, mutect2, varscan2
- ZNF641 | c.462C>T p.P154= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as COSV56391722; called by muse, mutect2, varscan2
- ZNF662 | c.687C>T p.F229= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as COSV60242391, COSV60243162; called by muse, mutect2, varscan2
- ZNF676 | c.154C>T p.L52= (on ENST00000650058; = p.L20= on NM_001001411.3) | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as rs201235589, COSV68092257, COSV68093380; called by muse, mutect2, varscan2
- ZSCAN5A | c.582G>A p.R194= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs1208693820, COSV54223764, COSV54225501; called by muse, mutect2, varscan2
- ZSCAN5B | c.1263C>T p.A421= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs1339758369, COSV62001246; called by muse, mutect2, varscan2
- ZWILCH | c.1269T>C p.I423= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs766096814, COSV57183372; called by muse, mutect2, varscan2
- FOLH1B | n.1926C>T | RNA (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847765 G>A | 5'Flank (SNP) | VAF 51/245 reads (21%) | catalogued as rs1174921806; called by muse, mutect2, varscan2
- NBPF7 | n.791G>A | RNA (SNP) | VAF 40/152 reads (26%) | called by muse, mutect2
- NXF5 | n.1245G>A | RNA (SNP) | VAF 70/109 reads (64%) | catalogued as COSV53793661; called by muse, mutect2, varscan2
- OR2U1P | n.465G>A | RNA (SNP) | VAF 71/226 reads (31%) | catalogued as rs368413594; called by muse, mutect2, varscan2
- OR56B4 | c.*1C>T | 3'UTR (SNP) | VAF 54/104 reads (52%) | catalogued as rs1288980918, COSV100337701; called by muse, mutect2, varscan2
- PXN | c.831+1535A>G | Intron (SNP) | VAF 5/16 reads (31%) | catalogued as COSV57221989; called by muse, mutect2, varscan2
- RBM44 | c.-98-2092G>A | Intron (SNP) | VAF 38/89 reads (43%) | catalogued as rs750596353, COSV57631294; called by muse, mutect2, varscan2
- RPL13A | c.256+98C>T | Intron (SNP) | VAF 14/72 reads (19%) | catalogued as COSV99201364; called by muse, mutect2, varscan2
- SLC22A17 | n.1118G>T | RNA (SNP) | VAF 37/93 reads (40%) | catalogued as COSV52837615; called by muse, mutect2, varscan2
- SLC3A2 | chr11:62852997 G>A | 5'Flank (SNP) | VAF 34/83 reads (41%) | catalogued as rs772253656; called by muse, mutect2, varscan2
- SNORD116-8 | n.73C>T | RNA (SNP) | VAF 50/178 reads (28%) | catalogued as rs760978777; called by muse, mutect2, varscan2
- TMEM52B | c.*1T>G | 3'UTR (SNP) | VAF 22/63 reads (35%) | catalogued as rs999917323, COSV100046546; called by muse, mutect2, varscan2
- ZNF99 | c.*150C>T | 3'UTR (SNP) | VAF 8/65 reads (12%) | catalogued as COSV101233985; called by muse, mutect2, varscan2
